Somatic mutation profile of tumor specimen ALCH-B28E-TTP1-A (aliquot ALCH-B28E-TTP1-A-1-0-D-A775-36) from ALCHEMIST case ALCH-B28E, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.1 years (22,697 days).
Specimen ALCH-B28E-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3bf10fd-fe43-473e-856d-7dd4ac2d968a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B28E-NB1-A (Blood Derived Normal), aliquot ALCH-B28E-NB1-A-1-0-D-A775-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8f24314-d885-46fc-9cc9-44172df7abd9

The open-access MAF lists 8 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRM7 | c.2036G>A p.R679Q | Missense Mutation (SNP) | VAF 13/371 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63128926; called by muse, mutect2
- AKT3 | c.909G>A p.M303I | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.145); called by muse, mutect2
- DOCK8 | c.275A>G p.D92G | Missense Mutation (SNP) | VAF 13/286 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.134); called by muse, mutect2
- HECTD4 | c.8628C>T p.F2876= | Silent (SNP) | VAF 13/265 reads (5%) | catalogued as rs1168253720, COSV101107252; called by muse, mutect2
- HNRNPUL1 | c.864G>A p.L288= | Silent (SNP) | VAF 14/269 reads (5%) | called by muse, mutect2
- MUC5AC | c.14328T>C p.A4776= | Silent (SNP) | VAF 7/125 reads (6%) | called by muse, mutect2
- ZNF236 | c.570C>T p.I190= | Silent (SNP) | VAF 14/304 reads (5%) | catalogued as rs771741183, COSV53495967; called by muse, mutect2
- TMPRSS3 | c.*89C>T | 3'UTR (SNP) | VAF 21/331 reads (6%) | catalogued as rs772188430; called by muse, mutect2
